Somatic mutation profile of tumor specimen TCGA-EL-A3H1-01A (aliquot TCGA-EL-A3H1-01A-11D-A21A-08) from TCGA case TCGA-EL-A3H1, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 66.6 years (24,328 days).
Specimen TCGA-EL-A3H1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93f62ebe-282a-4c71-bc0d-e772e84df6b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3H1-11A (Solid Tissue Normal), aliquot TCGA-EL-A3H1-11A-11D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f6d95a8-edb9-4cfd-b7fd-9405524feaad

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 13, Silent 5, Frame Shift Ins 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM5 | c.546A>C p.E182D | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV59375427; called by muse, mutect2, varscan2
- ANKMY1 | c.2166C>A p.N722K | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56042102; called by muse, mutect2, varscan2
- CHD3 | c.1809G>C p.K603N | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.656); catalogued as COSV57881246; called by muse, mutect2, varscan2
- CHD4 | c.4436T>G p.V1479G (on ENST00000357008 / NM_001363606.2; = p.V1492G on NM_001273.5) | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58912277; called by muse, mutect2
- FBN1 | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.321); catalogued as rs1555399258, COSV57332441; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GBP5 | c.681C>G p.F227L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV100600113, COSV58592119, COSV58594577; called by muse, mutect2
- GPR151 | c.454T>G p.Y152D | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV57042671; called by muse, mutect2, varscan2
- MPPED1 | c.787G>A p.G263S | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs757747745, COSV68839443; called by muse, mutect2, varscan2
- PLXNB3 | c.4858C>T p.L1620F | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1557064580, COSV62803008; called by muse, mutect2, varscan2
- PRTG | c.2953C>T p.Q985* | Nonsense Mutation (SNP) | VAF 3/21 reads (14%) | catalogued as COSV101221337; called by muse, varscan2
- PSMC3IP | c.586A>C p.K196Q (on ENST00000393795 / NM_016556.4; = p.K184Q on NM_013290.6) | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs374511642; called by muse, varscan2
- SCN3A | c.5004C>G p.I1668M | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV51826842; called by muse, mutect2, varscan2
- SH2D3C | c.1729A>T p.K577* (on ENST00000314830 / NM_170600.3; = p.K420* on NM_005489.4) | Nonsense Mutation (SNP) | VAF 20/147 reads (14%) | catalogued as COSV59130730; called by muse, mutect2, varscan2
- STRA6 | c.1281G>C p.Q427H | Missense Mutation (SNP) | VAF 108/240 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV60589043; called by muse, mutect2, varscan2
- ZNF410 | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.932); catalogued as COSV57912483; called by muse, mutect2, varscan2
- SPRR2E | c.89dup p.K31Efs*4 | Frame Shift Ins (INS) | VAF 70/430 reads (16%) | called by pindel, varscan2
- TG | c.5673dup p.W1892Mfs*38 | Frame Shift Ins (INS) | VAF 20/56 reads (36%) | called by mutect2, pindel, varscan2
- ABCG5 | c.573G>A p.G191= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV53213849; called by muse, mutect2, varscan2
- BRF2 | c.219C>T p.L73= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV55105873; called by muse, mutect2, varscan2
- CETP | c.1191C>T p.L397= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV52364636; called by muse, mutect2, varscan2
- DKC1 | c.1314T>A p.V438= | Silent (SNP) | VAF 50/107 reads (47%) | catalogued as COSV65730348; called by muse, mutect2, varscan2
- SEPTIN6 | c.327C>A p.I109= | Silent (SNP) | VAF 24/422 reads (6%) | catalogued as rs1390463159, COSV59718195; called by muse, mutect2
